Surgical pathology report (de-identified scan), TCGA case TCGA-CV-7568, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-CV-7568-01A (Primary Tumor).

[page 1 of 2]
THIS REPORT HAS BEEN AMENDED

SUPPLEMENTAL REPORT

DIAGNOSIS :

(C) FLOOR OF MOUTH MASS, COMPOSITE RESECTION:

INVASIVE SQUAMOUS CARCINOMA WITH ADENOID AND SARCOMATOID
FEATURES, MODERATELY TO POORLY DIFFERENTIATED,
(5.5 CM IN GREATEST DIMENTION), INVADING MUSCLE AND BONE WITH VASCULAR AND
PERINEURAL INVASION, Margins of resection free of tumor.

COMMENT: This supplemental report is being issued to report the presence of bone
involvement.

COMMENT

This report has been amended by [REDACTED] to correct the anatomic site
for specimen C from "mandible" to "floor of mouth tumor, composite resection".

DIAGNOSIS

(A) LEFT SUPRAOMOHYOID NECK DISSECTION:

Ten lymph nodes, negative for tumor (0/4 submental/submaxillary
(level 1); 0/2 subdigastric (level 2); 0/3 midjugular (level 3);
0/1 lower jugular (level 4).

(B) RIGHT MODIFIED NECK DISSECTION:

METASTATIC SQUAMOUS CELL CARCINOMA IN 1 OF 3 LYMPH NODES
1/1 subdigastric (level 2); 0/1 midjugular (level 3);
0/1 lower jugular (level 4).

(C) COMPOSITE RESECTION ANTERIOR MANDIBLE FLOOR OF MOUTH:

INVASIVE SARCOMATOID SQUAMOUS CELL CARCINOMA WITH ADENOID
SQUAMOUS CELL COMPONENT, MODERATELY DIFFERENTIATED,
KERATINIZING; (5.5 X 3.0 X 1.5 CM) INVADING THROUGH MUSCLE
TO UNDERLYING BONE (SEE COMMENT).

[page 2 of 2]
VASCULAR AND PERINEURAL INVASION IDENTIFIED.
Margins free of tumor.

- (D) MENTAL SKIN:
Skin, no tumor present.
- (E) RIGHT LOWER LIP:
Squamous mucosa, no tumor present.
- (F) ANTERIOR FLOOR OF MOUTH:
Squamous mucosa, no tumor present.
- (G) BUCCAL MUCOSA, LEFT:
Squamous mucosa, no tumor present.
- (H) RIGHT BUCCAL MUCOSA:
Squamous mucosa, no tumor present.
- (I) TEETH:
Teeth, gross diagnosis only.

COMMENT

A supplemental report will follow for part C to describe the degree of bone involvement.

SPECIMEN

- (A) LEFT SUPRAOMOHYOID NECK DISSECTION:
- (B) RIGHT MODIFIED NECK DISSECTION:
- (C) COMPOSITE RESECTION ANTERIOR MANDIBLE FLOOR OF MOUTH:
- (D) MENTAL SKIN:
- (E) RIGHT LOWER LIP:
- (F) ANTERIOR FLOOR OF MOUTH:
- (G) BUCCAL MUCOSA, LEFT:
- (H) RIGHT BUCCAL MUCOSA:
- (I) TEETH:

SNOMED CODES

T-11180,M-80743

Entire report and diagnosis completed by

Source: NCI Genomic Data Commons file f714581d-2579-4069-9854-a1d56313444c (TCGA-CV-7568.FDB52839-AF42-4070-8C6D-B07321EF934A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).